HCMI case HCM-CSHL-0875-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f8c9dead-9a29-44a3-9680-794bf660b383

Demographics
Sex at birth: female; Days to birth: -25,915 days (71.0 years before the index date); Year of birth: 1948; Vital status: Dead; Days to death: 69 days.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N2; Tumor grade: G3; Prior treatment: Yes.
   Pathology details: Lymph nodes positive: 5; Lymph nodes tested: 5; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 69.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 168 cm; BMI: 23.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0875-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0875-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
